Gene-level copy-number profile of specimen HCM-WCMC-1340-C54-85A from HCMI case HCM-WCMC-1340-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage I; FIGO stage: Stage IIIA; Age at diagnosis: 64.0 years (23,370 days).
Specimen HCM-WCMC-1340-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e94b520c-20fe-4ca2-9b85-7c6e5c049bee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1340-C54-12A (saliva); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/38841a3b-387b-433e-9972-dacf9c658941

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 8,458; copy number 2: 43,544; copy number 3: 5,296; copy number 4: 765; copy number 5: 50; copy number 6: 51; copy number 7: 176; copy number 8: 47.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 324 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:224,896,262–225,399,292, 1 gene, copy number 5: DNAH14.
- chr1:232,700,204–233,836,432, 15 genes, copy number 5: RNU6-1211P, LINC01745, LINC01744, MAP10, RNU1-74P, AL122003.1, NTPCR, PCNX2, RPS7P3, AL133380.1, MAP3K21, RNU4-77P, KCNK1, MIR4427, AL663058.1.
- chr1:241,590,102–241,802,133, 4 genes, copy number 5 (within-gene range 3–5): OPN3, CHML, AL133390.1, WDR64.
- chr13:95,336,106–95,394,454, 2 genes, copy number 5: RNY4P27, MEMO1P5.
- chr17:74,922,950–75,289,510, 28 genes, copy number 5 (within-gene range 3–5): OTOP2, OTOP3, HID1, HID1-AS1, CDR2L, MRPL58, RNU6-362P, KCTD2, ATP5PD, RN7SL573P, AC111186.1, TRIM80P, SLC16A5, Y_RNA, ARMC7, NT5C, AC022211.4, JPT1, AC022211.3, AC022211.1, Y_RNA, SUMO2, NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19.
- chr19:27,638,483–36,331,770, 274 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,456. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
